Somatic mutation profile of tumor specimen TCGA-CZ-5453-01A (aliquot TCGA-CZ-5453-01A-01D-1501-10) from TCGA case TCGA-CZ-5453, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 67.5 years (24,640 days).
Specimen TCGA-CZ-5453-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d2c14b2-1df4-46d6-9b5b-ffe516143f07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5453-11A (Solid Tissue Normal), aliquot TCGA-CZ-5453-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/309aae79-5803-4a45-b18b-e9417b453f35

The open-access MAF lists 80 somatic variants for this specimen: 61 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 16, Frame Shift Del 8, Splice Site 4, Nonsense Mutation 3, 3'UTR 2, In Frame Del 2, Translation Start Site 1, Splice Region 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP2 | c.392A>T p.N131I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57044022; called by muse, mutect2, varscan2
- AKR1B1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1227903553, COSV53648840; called by muse, mutect2, varscan2
- AMZ2 | c.854C>A p.P285H | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63083722; called by muse, mutect2, varscan2
- ANKK1 | c.2079G>T p.W693C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as COSV100393094, COSV58274267; called by muse, varscan2
- ARHGAP20 | c.1261C>A p.H421N | Missense Mutation (SNP) | VAF 30/604 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV52819236; called by muse, mutect2
- ATP11A | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV52124339; called by muse, mutect2, varscan2
- AUH | c.418+1G>A p.X140_splice | Splice Site (SNP) | VAF 42/621 reads (7%) | catalogued as COSV57866087; called by muse, mutect2
- BACE1 | c.185A>G p.E62G | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.08); catalogued as COSV100475345; called by muse, mutect2, varscan2
- BRD1 | c.2137G>A p.G713S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV53461575; called by muse, mutect2, varscan2
- CAMK2G | c.1505T>C p.I502T (on ENST00000423381 / NM_001367518.1; = p.I439T on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs778095008, COSV55217880; called by muse, mutect2, varscan2
- CCAR1 | c.331G>T p.V111F | Missense Mutation (SNP) | VAF 201/517 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56274430; called by muse, mutect2, varscan2
- CLSPN | c.2392del p.S798Vfs*39 | Frame Shift Del (DEL) | VAF 78/264 reads (30%) | catalogued as COSV52046833; called by mutect2, pindel
- CMYA5 | c.3344C>G p.T1115S | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV71409463; called by muse, mutect2
- CPLX2 | c.143G>C p.R48P | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV64002220; called by muse, mutect2, varscan2
- DLX6 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs763456945, COSV50292799; called by muse, mutect2, varscan2
- DNAJC3 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 200/485 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as COSV65133086; called by muse, mutect2, varscan2
- DRD2 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 12/253 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs987305741, COSV60760478, COSV60762832; called by muse, mutect2
- EPHX1 | c.980A>G p.E327G | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55304053; called by muse, varscan2
- FOSB | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1267780132, COSV62279268; called by muse, mutect2, varscan2
- GALE | c.472G>C p.G158R | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52527425; called by muse, mutect2
- GPR26 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.543); catalogued as rs770105456, COSV52934473; called by muse, mutect2, varscan2
- IPO13 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64895059; called by muse, mutect2, varscan2
- LSP1 | c.991G>T p.V331L | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV61137474; called by muse, mutect2, varscan2
- MINAR1 | c.218T>A p.V73E | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.057); catalogued as COSV59584905, COSV59586523; called by muse, mutect2, varscan2
- MRPL54 | c.266A>T p.D89V | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV57463702; called by muse, mutect2, varscan2
- NNT | c.3088C>A p.L1030I | Missense Mutation (SNP) | VAF 128/361 reads (35%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.978); catalogued as COSV52929686; called by muse, mutect2, varscan2
- OCEL1 | c.594C>G p.S198R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV52245518; called by mutect2, varscan2
- OSBPL9 | c.1566T>A p.H522Q | Missense Mutation (SNP) | VAF 179/437 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV61874952; called by muse, mutect2, varscan2
- PBRM1 | c.994del p.R332Vfs*30 | Frame Shift Del (DEL) | VAF 166/339 reads (49%) | catalogued as COSV56299114; called by mutect2, pindel, varscan2
- PBXIP1 | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63777711; called by muse, mutect2, varscan2
- PDCD2L | c.687-2A>C p.X229_splice | Splice Site (SNP) | VAF 138/371 reads (37%) | catalogued as COSV55826669; called by muse, mutect2, varscan2
- POLR3C | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 89/234 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1294806687, COSV61937541; called by muse, mutect2, varscan2
- POT1 | c.546+2T>A p.X182_splice | Splice Site (SNP) | VAF 43/134 reads (32%) | catalogued as COSV62934703; called by muse, mutect2, varscan2
- RENBP | c.1043T>C p.L348P | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.863); catalogued as COSV64170605; called by muse, mutect2, varscan2
- SAMD8 | c.20T>A p.L7H | Missense Mutation (SNP) | VAF 107/275 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.533); catalogued as COSV101014197; called by muse, mutect2, varscan2
- SEMA4B | c.1457T>A p.I486N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60175888; called by muse, mutect2, varscan2
- SLC15A4 | c.1039C>T p.L347F | Missense Mutation (SNP) | VAF 268/738 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV57163816; called by muse, mutect2
- SLC15A4 | c.1037G>T p.S346I | Missense Mutation (SNP) | VAF 264/730 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV57163825; called by muse, mutect2
- SLC28A1 | c.606G>T p.V202= | Splice Region (SNP) | VAF 23/318 reads (7%) | catalogued as COSV54485984; called by muse, mutect2
- SLC5A4 | c.664G>C p.A222P | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV56673901; called by muse, mutect2
- SLC9C1 | c.2033T>G p.F678C | Missense Mutation (SNP) | VAF 192/331 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV59893412; called by muse, mutect2, varscan2
- SLCO4C1 | c.1331C>G p.S444* | Nonsense Mutation (SNP) | VAF 180/449 reads (40%) | catalogued as COSV60520262; called by muse, mutect2, varscan2
- STC2 | c.620T>C p.I207T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.093); catalogued as COSV54182139; called by muse, mutect2, varscan2
- TANK | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 168/423 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759803420, COSV52045942; called by muse, mutect2, varscan2
- TENT4B | c.1900C>T p.Q634* (on ENST00000561678 / NM_001365323.2; = p.Q619* on NM_001040284.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 121/275 reads (44%) | catalogued as COSV100666156, COSV62549398; called by muse, mutect2, varscan2
- TMPRSS11F | c.11+1G>A p.X4_splice | Splice Site (SNP) | VAF 141/346 reads (41%) | catalogued as rs148740696, COSV62469508; called by muse, mutect2, varscan2
- TNNT1 | c.622G>C p.A208P | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs1282226777, COSV52573552; called by muse, mutect2
- TSPAN5 | c.239G>A p.C80Y | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59877383; called by muse, mutect2, varscan2
- USP42 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 234/407 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV60364353; called by muse, mutect2, varscan2
- VHL | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 51/74 reads (69%) | catalogued as CM982011, COSV56543469, COSV56551494; called by muse, mutect2, varscan2
- ZMYM2 | c.3103G>C p.E1035Q | Missense Mutation (SNP) | VAF 121/917 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as COSV67037587; called by muse, mutect2, varscan2
- ZRANB1 | c.1283T>C p.L428S | Missense Mutation (SNP) | VAF 99/280 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV62844086; called by muse, mutect2
- BOD1L1 | c.7250_7251del p.S2417Cfs*57 | Frame Shift Del (DEL) | VAF 40/144 reads (28%) | called by pindel, varscan2
- BRD4 | c.698_701delinsA p.I233_V234delinsN | In Frame Del (DEL) | VAF 13/29 reads (45%) | called by pindel, varscan2*
- CCDC159 | c.692_693dup p.A232Lfs*10 | Frame Shift Ins (INS) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- COL6A6 | c.6625del p.L2209Sfs*21 | Frame Shift Del (DEL) | VAF 154/334 reads (46%) | called by pindel, varscan2
- LARP1 | c.1826_1827del p.F609* (on ENST00000518297 / NM_033551.3; = p.F532* on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 77/251 reads (31%) | called by mutect2, pindel, varscan2
- MID1 | c.1425del p.E475Dfs*5 | Frame Shift Del (DEL) | VAF 40/64 reads (63%) | called by mutect2, pindel, varscan2
- NBN | c.1070del p.P357Qfs*2 | Frame Shift Del (DEL) | VAF 246/454 reads (54%) | called by mutect2, pindel, varscan2
- RSPRY1 | c.1465del p.M489* | Frame Shift Del (DEL) | VAF 219/701 reads (31%) | called by mutect2, pindel, varscan2
- ZMAT1 | c.1589_1601delinsT p.H530_H534delinsL | In Frame Del (DEL) | VAF 136/249 reads (55%) | called by pindel, varscan2*
- ADGRV1 | c.17331A>G p.L5777= | Silent (SNP) | VAF 135/356 reads (38%) | catalogued as rs753654482, COSV67995362; called by muse, mutect2, varscan2
- AGO2 | c.2250G>T p.L750= | Silent (SNP) | VAF 59/130 reads (45%) | catalogued as COSV55052705; called by muse, mutect2, varscan2
- ATE1 | c.150C>T p.L50= | Silent (SNP) | VAF 167/492 reads (34%) | catalogued as rs781034904, COSV56443180; called by muse, mutect2, varscan2
- CAD | c.3372C>T p.V1124= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV53031818; called by muse, mutect2, varscan2
- FCGR3B | c.519G>A p.R173= | Silent (SNP) | VAF 189/487 reads (39%) | catalogued as rs1010720514, COSV54211911; called by muse, mutect2, varscan2
- HIRIP3 | c.270G>A p.E90= | Silent (SNP) | VAF 56/136 reads (41%) | catalogued as rs761041939, COSV54231750; called by muse, mutect2, varscan2
- OR10H3 | c.402C>T p.N134= | Silent (SNP) | VAF 38/281 reads (14%) | catalogued as COSV59944832; called by muse, mutect2, varscan2
- REEP2 | c.60C>T p.A20= | Silent (SNP) | VAF 44/114 reads (39%) | catalogued as COSV54735899; called by muse, mutect2, varscan2
- SERPINB6 | c.396C>T p.F132= (on ENST00000612421 / NM_001271823.2; = p.F113= on NM_004568.6) | Silent (SNP) | VAF 30/747 reads (4%) | catalogued as COSV100177651, COSV59567534; called by muse, mutect2
- SLC7A6 | c.1071C>A p.S357= | Silent (SNP) | VAF 120/341 reads (35%) | catalogued as COSV50450729; called by muse, mutect2, varscan2
- SMARCA4 | c.1917G>T p.L639= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as COSV60809129; called by muse, mutect2, varscan2
- SNX8 | c.342G>A p.V114= | Silent (SNP) | VAF 64/117 reads (55%) | catalogued as COSV56130101; called by muse, mutect2, varscan2
- SURF6 | c.207C>T p.S69= | Silent (SNP) | VAF 64/178 reads (36%) | catalogued as rs782380646, COSV100790770, COSV100790797; called by muse, mutect2, varscan2
- TEX13A | c.66C>T p.N22= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as rs781800251, COSV61157959; called by muse, mutect2
- ZNF236 | c.2424G>A p.T808= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs759371892, COSV53496649, COSV53497768; called by muse, mutect2, varscan2
- ZSCAN29 | c.375A>G p.K125= | Silent (SNP) | VAF 46/129 reads (36%) | catalogued as rs1294630348, COSV53021476; called by muse, mutect2, varscan2
- ARHGAP42 | c.*3659A>G | 3'UTR (SNP) | VAF 90/225 reads (40%) | catalogued as COSV53986717; called by muse, mutect2, varscan2
- NANOS3 | chr19:13874875 G>A | 5'Flank (SNP) | VAF 14/39 reads (36%) | catalogued as rs373207013; called by muse, mutect2, varscan2
- SLMAP | c.*17C>G | 3'UTR (SNP) | VAF 56/106 reads (53%) | catalogued as COSV55853408; called by muse, mutect2
